Somatic mutation profile of tumor specimen C3L-03400-02 (aliquot CPT0224540010) from CPTAC case C3L-03400, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 38.4 years (14,028 days).
Specimen C3L-03400-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8e501c03-2099-4e81-94a6-3ffc75c5a2df.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03400-31 (Blood Derived Normal), aliquot CPT0226220002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1b2986a0-3179-45c3-8834-f9762ded6b44

The open-access MAF lists 48 somatic variants for this specimen: 33 protein-altering or splice-affecting, 12 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 12, Nonsense Mutation 2, Intron 1, 3'UTR 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.1498+1G>A p.X500_splice | Splice Site (SNP) | VAF 44/169 reads (26%) | hotspot (GDC flag); catalogued as rs1131690909, CS058010, CS143244, COSV57297471, COSV57311354, COSV57331286, COSV57332387; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 163/495 reads (33%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- COL5A1 | c.4705C>T p.P1569S | Missense Mutation (SNP) | VAF 42/170 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.966); catalogued as rs1314380963, COSV100880146; called by muse, mutect2, varscan2
- EPB41L3 | c.1840A>T p.T614S | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV59448486; called by muse, mutect2, varscan2
- ITIH6 | c.1433G>A p.R478H | Missense Mutation (SNP) | VAF 49/249 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs775332002, COSV54488908; called by muse, mutect2, varscan2
- LCE3E | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 121/631 reads (19%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs1398597048, COSV64232333; called by muse, mutect2, varscan2
- PLCG1 | c.3487G>A p.E1163K | Missense Mutation (SNP) | VAF 44/285 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV54815150; called by muse, mutect2, varscan2
- PPP1R13L | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 40/258 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs777101661; called by muse, mutect2, varscan2
- PROKR1 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 89/453 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.135); catalogued as rs763039330; called by muse, mutect2, varscan2
- PTEN | c.286C>A p.P96T | Missense Mutation (SNP) | VAF 62/277 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64297602, COSV64303463, COSV64307402; called by muse, mutect2, varscan2
- RICTOR | c.2401G>A p.G801S | Missense Mutation (SNP) | VAF 20/271 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1189960227; called by muse, mutect2
- UACA | c.561A>G p.I187M | Missense Mutation (SNP) | VAF 19/262 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs139165884; called by muse, mutect2
- ARHGEF10L | c.1630A>C p.T544P | Missense Mutation (SNP) | VAF 21/445 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2
- C3orf18 | c.246C>G p.I82M | Missense Mutation (SNP) | VAF 35/184 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CD300C | c.607C>T p.L203F | Missense Mutation (SNP) | VAF 44/354 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- DAG1 | c.780G>A p.W260* | Nonsense Mutation (SNP) | VAF 55/739 reads (7%) | called by muse, mutect2
- DNAJC13 | c.4048T>C p.Y1350H | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DSP | c.1541C>T p.P514L | Missense Mutation (SNP) | VAF 145/419 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HCN3 | c.2155C>G p.L719V | Missense Mutation (SNP) | VAF 23/312 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2
- HERC2 | c.583G>A p.V195M | Missense Mutation (SNP) | VAF 31/346 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- KMT2D | c.6793G>A p.G2265R | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- LRP3 | c.1241C>T p.P414L | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- MAST1 | c.725C>T p.T242M | Missense Mutation (SNP) | VAF 70/510 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- MAX | c.184C>T p.Q62* | Nonsense Mutation (SNP) | VAF 16/546 reads (3%) | called by muse, mutect2
- MUC5B | c.6473T>G p.I2158S | Missense Mutation (SNP) | VAF 95/547 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NFATC1 | c.710C>G p.S237C | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PIBF1 | c.833T>C p.V278A | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PIEZO2 | c.1960G>A p.E654K | Missense Mutation (SNP) | VAF 32/336 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2
- RBM10 | c.1436G>T p.G479V | Missense Mutation (SNP) | VAF 91/528 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.116); called by mutect2, varscan2
- SH3TC1 | c.2509C>T p.L837F | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SLC7A13 | c.1280T>C p.L427P | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TASOR | c.2546A>G p.D849G (on ENST00000355628 / NM_001365636.2; = p.D453G on NM_015224.3) | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- TENM4 | c.7282T>C p.W2428R | Missense Mutation (SNP) | VAF 87/447 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADAMTS5 | c.2640C>A p.V880= | Silent (SNP) | VAF 45/209 reads (22%) | catalogued as COSV53176881; called by muse, mutect2, varscan2
- CCDC116 | c.1098C>T p.P366= | Silent (SNP) | VAF 35/149 reads (23%) | catalogued as rs758843817; called by muse, mutect2, varscan2
- CDHR3 | c.2328C>T p.I776= | Silent (SNP) | VAF 19/221 reads (9%) | catalogued as COSV100487812, COSV58418236; called by muse, mutect2
- CNTN5 | c.3141A>T p.A1047= | Silent (SNP) | VAF 13/94 reads (14%) | called by muse, mutect2, varscan2
- FEM1A | c.1782G>A p.P594= | Silent (SNP) | VAF 147/740 reads (20%) | catalogued as rs972697373, COSV54165141; called by muse, mutect2, varscan2
- MYH4 | c.1824G>A p.V608= | Silent (SNP) | VAF 86/226 reads (38%) | catalogued as rs1187069845; called by muse, mutect2, varscan2
- PCDHGC4 | c.1176C>T p.H392= | Silent (SNP) | VAF 47/287 reads (16%) | catalogued as COSV99339946; called by muse, mutect2, varscan2
- POLRMT | c.207G>A p.R69= | Silent (SNP) | VAF 25/123 reads (20%) | catalogued as rs747583919; called by muse, mutect2, varscan2
- TMEM70 | c.508T>C p.L170= | Silent (SNP) | VAF 22/756 reads (3%) | called by muse, mutect2
- TTF2 | c.2517A>G p.K839= | Silent (SNP) | VAF 54/271 reads (20%) | called by muse, mutect2, varscan2
- VPS51 | c.765G>A p.V255= | Silent (SNP) | VAF 42/547 reads (8%) | called by muse, mutect2
- ZNF99 | c.1524T>A p.P508= | Silent (SNP) | VAF 78/449 reads (17%) | catalogued as COSV68055175, COSV68056526; called by muse, mutect2, varscan2
- PPP4R1L | n.1794C>T | RNA (SNP) | VAF 30/151 reads (20%) | catalogued as rs753192944; called by muse, mutect2, varscan2
- UGT1A6 | c.862-12249C>T | Intron (SNP) | VAF 72/388 reads (19%) | called by muse, mutect2, varscan2
- URAD | c.*7C>T | 3'UTR (SNP) | VAF 45/285 reads (16%) | called by muse, mutect2, varscan2
